Gene-level copy-number profile of tumor specimen CUPP-B4OA-TTM1-A from CCG case CUPP-B4OA, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.2 years (15,063 days).
Specimen CUPP-B4OA-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fa38039d-26f9-4b3c-909e-0eb4df85c2df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4OA-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/d8c6f94d-b24f-4743-aa90-cc1b6c5a4a2e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 16,257; copy number 2: 33,332; copy number 3: 6,621; copy number 4: 1,116; copy number 5: 492; copy number 6: 528; copy number 7: 1; copy number 8: 4; copy number 11: 6; copy number 13: 1; copy number 18: 1; copy number 19: 6.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,199,823–10,200,672, 1 gene: AC006499.1.
- chr8:20,113,343–20,950,175, 12 genes (within-gene range 0–1): RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1, TMEM97P2, AC015468.3.
- chr10:100,969,458–100,994,403, 5 genes: MRPL43, SEMA4G, MIR608, AL133215.1, TWNK.
- chr19:4,229,523–4,237,528, 1 gene: EBI3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,039 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:198,523,222–198,598,868, 2 genes, copy number 5: ATP6V1G3, AL157402.1.
- chr1:235,131,634–235,328,219, 1 gene, copy number 5 (within-gene range 3–5): ARID4B.
- chr1:235,295,865–235,296,335, 1 gene, copy number 5: RPL23AP23.
- chr2:142,131,178–142,137,830, 1 gene, copy number 5 (within-gene range 2–5): AC078882.1.
- chr3:93,843,764–123,274,136, 420 genes, copy number 5–19 (broad region; genes not listed).
- chr5:181,178,821–181,191,852, 1 gene, copy number 13: LINC01962.
- chr7:2,234,195–2,664,802, 15 genes, copy number 6: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3.
- chr19:27,638,483–42,652,355, 592 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:48,364,367–48,391,551, 2 genes, copy number 5: SYNGR4, KDELR1.
- chr19:48,445,841–48,457,022, 1 gene, copy number 5 (within-gene range 4–5): GRWD1.
- chr19:48,485,271–48,513,935, 1 gene, copy number 5: LMTK3.
- chr22:49,845,929–49,846,720, 2 genes, copy number 5: AL117328.1, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 16,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
